Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2S, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2S-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-O-3
Fibromyosarcoma 8811/3
Site: Back NOS @49.6
JW 5/10/14

....

Clinical Diagnosis & History:

Patient with left paraspinal spindle cell neoplasm.

Specimens Submitted:

- 1: SP: Left paraspinal mass
- 2: SP: Normal fat

DIAGNOSIS:

- 1) SOFT TISSUE, LEFT PARASPINAL; EXCISION:
- HIGH GRADE MYXOFIBROSARCOMA INVOLVING FIBROADIPOSE TISSUE AND SKELETAL MUSCLE, 7.9 CM GREATEST DIMENSION.
- INTRATUMORAL LYMPHOID AND HISTIOCYTIC AGGREGATES ARE PROMINENT IN SOME SECTIONS.
- TUMOR COMES WITHIN 0.5 CM OF DEEP MARGIN; ALL OTHER MARGINS ARE WIDELY CLEAR.
- CHANGES CONSISTENT WITH PRIOR BIOPSY [REDACTED].

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, previously incised and inked, labeled "Left paraspinal mass, short stitch superior, long stitch lateral" and consists of a piece of white-tan skin and subcutaneous tissue measuring 21.2 x 12.6 x 6.8 cm. A short stitch indicates the superior aspect, and a long stitch indicates the lateral aspect. The skin ellipse is white-tan and measures 20.7 x 3.6 cm, with a centrally located pink white linear scar measuring 5.3 x 0.3 cm and located 1.7 cm from the nearest skin margin. The underlying tissue consists of a mass surrounded by red tan skeletal muscle and yellow-tan soft tissue. The specimen is previously cross-sectioned to

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
reveal a movable pseudo-encapsulated fleshy rubbery glistening tumor mass measuring 7.9 x 7.1 x 6.9 cm. The mass is surrounded by skeletal muscle and soft tissue and appears closest to the deep margin, located up to 0.3 cm from the inked deep surface, toward the medial aspect. The remaining margins are grossly free by at least 0.6 cm. On cut section, the mass shows a primarily fleshy cut surface with streaky pale yellow, pale creamy tan, and focally hemorrhagic areas noted. The anterior surface is inked red, the medial surface blue, the lateral surface green, the superior and deep margins black, and the inferior yellow. Sections through the remaining tissue reveal red-tan skeletal muscle, areas of yellow tan soft tissue, and thin bands of white tan tissue. Representative sections are submitted to TPS, for permanent section, and photographs are taken.

Summary of sections:

S superior margin perpendicular section
M medial margin perpendicular section
I inferior margin perpendicular section
L lateral margin perpendicular section
D deep with tumor, perpendicular section
A anterior margin perpendicular section
SK skin
T tumor

2) The specimen is received in formalin, labeled "Normal fat". It consists of a fragment of adipose tissue measuring 2.5 x 2 x 0.5 cm. Entirely submitted for TPS.

Summary of Sections:

Part 1: SP: Left paraspinal mass

Block	Sect.	Site	PCs
1		a	1
3		d	3
1		i	1
1		l	1
1		m	1
1		s	1
1		sk	1
8		t	8

Part 2: SP: Normal fat

** End of Report **

Source: NCI Genomic Data Commons file b0eed175-d77f-4232-beae-febdbb39251b (TCGA-DX-AB2S.39F03D40-22C5-4937-88F1-78D332067FE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).